Somatic mutation profile of tumor specimen TCGA-ZT-A8OM-01A (aliquot TCGA-ZT-A8OM-01A-11D-A428-09) from TCGA case TCGA-ZT-A8OM, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type A, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 73.7 years (26,923 days).
Specimen TCGA-ZT-A8OM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01a4caa0-66f6-4aae-b4fc-31c09fb7f93f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZT-A8OM-10A (Blood Derived Normal), aliquot TCGA-ZT-A8OM-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a1c2068-ac5d-4db8-ad71-1c221a6e1922

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 22/591 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- BRWD3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs760487609, COSV100956595; called by muse, mutect2
- CAPRIN1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100403709, COSV58219658; called by muse, mutect2, varscan2
- CBLL2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV60368273; called by muse, mutect2
- STAT6 | c.829A>C p.K277Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104411262; called by muse, mutect2, varscan2
- ZNF791 | c.872A>C p.E291A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs1271014472, COSV58480164; called by muse, mutect2
- BFSP2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- CELF5 | c.1397_1405del p.I466_M468del | In Frame Del (DEL) | VAF 8/100 reads (8%) | called by mutect2, pindel
- EFCAB5 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MME | c.234G>A p.E78= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs201425951; called by muse, mutect2, varscan2
- NR1D2 | c.1566C>A p.V522= | Silent (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- TPR | c.3588T>A p.I1196= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
